Somatic mutation profile of tumor specimen TCGA-AA-3534-01A (aliquot TCGA-AA-3534-01A-01D-1953-10) from TCGA case TCGA-AA-3534, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 78.0 years (28,489 days).
Specimen TCGA-AA-3534-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 90846225-9fca-41f0-be2c-93a08cfe8926.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3534-11A (Solid Tissue Normal), aliquot TCGA-AA-3534-11A-01D-1554-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1d50997e-d042-4498-8822-59fb613cc93d

The open-access MAF lists 32 somatic variants for this specimen: 20 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 17, Silent 12, Splice Site 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP3D1 | c.1106C>T p.S369F | Missense Mutation (SNP) | VAF 132/363 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100642882; called by muse, mutect2, varscan2
- ARHGEF18 | c.2789G>A p.G930E (on ENST00000359920 / NM_001130955.2; = p.G826E on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100149831; called by muse, mutect2, varscan2
- CEBPE | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.585); catalogued as COSV99247639; called by muse, mutect2, varscan2
- DPY19L4 | c.1101+1G>A p.X367_splice | Splice Site (SNP) | VAF 7/17 reads (41%) | catalogued as COSV101363419; called by muse, mutect2, varscan2
- ELFN2 | c.1450G>A p.A484T | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs140163106; called by muse, mutect2, varscan2
- HPCAL1 | c.454A>G p.I152V | Missense Mutation (SNP) | VAF 122/531 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV100324154; called by muse, mutect2, varscan2
- HYDIN | c.4579G>A p.E1527K | Missense Mutation (SNP) | VAF 200/687 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV101157958; called by muse, mutect2, varscan2
- KIFC3 | c.265G>A p.V89M | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.945); catalogued as rs782516355, COSV65551577; called by muse, mutect2, varscan2
- OPRL1 | c.308C>T p.T103M | Missense Mutation (SNP) | VAF 118/213 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745570699, COSV100402206; called by muse, mutect2, varscan2
- OTUD7A | c.1936G>A p.G646S (on ENST00000307050 / NM_001382637.1; = p.G639S on NM_130901.3) | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.123); catalogued as COSV100192948; called by muse, mutect2, varscan2
- PANX2 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV50314562; called by muse, mutect2, varscan2
- PTPRT | c.3563G>A p.R1188H | Missense Mutation (SNP) | VAF 91/319 reads (29%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.791); catalogued as rs753788938, COSV61973804; called by muse, mutect2, varscan2
- RGS19 | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs577731145, COSV58659410; called by muse, mutect2, varscan2
- RTP5 | c.661G>A p.G221S | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.217); catalogued as COSV58319982; called by muse, mutect2, varscan2
- SOX9 | c.340G>T p.V114L | Missense Mutation (SNP) | VAF 37/46 reads (80%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as COSV99818633; called by muse, mutect2, varscan2
- USF3 | c.4376A>G p.Y1459C | Missense Mutation (SNP) | VAF 64/173 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100325619; called by muse, mutect2, varscan2
- VAX1 | c.403C>T p.R135W | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143950742; called by muse, mutect2, varscan2
- WDPCP | c.1813-2A>G p.X605_splice | Splice Site (SNP) | VAF 240/462 reads (52%) | catalogued as COSV99706259; called by muse, mutect2, varscan2
- WSCD1 | c.1591C>T p.R531C | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as rs1394035623, COSV58493531; called by muse, mutect2, varscan2
- ZFP36L2 | c.478dup p.R160Pfs*314 | Frame Shift Ins (INS) | VAF 15/61 reads (25%) | called by mutect2, pindel, varscan2
- DCAF12L1 | c.1128C>T p.D376= | Silent (SNP) | VAF 33/104 reads (32%) | catalogued as COSV100948392; called by muse, mutect2, varscan2
- DHX30 | c.2796C>T p.S932= (on ENST00000445061 / NM_138615.3; = p.S893= on NM_014966.3) | Silent (SNP) | VAF 33/77 reads (43%) | catalogued as rs150015186; called by muse, mutect2, varscan2
- DMRTA1 | c.87G>A p.P29= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV100364830; called by muse, mutect2, varscan2
- DND1 | c.303C>A p.A101= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs200268202, COSV56905337; called by mutect2, varscan2
- EVL | c.645C>T p.H215= (on ENST00000402714 / NM_001330221.2; = p.H217= on NM_016337.3) | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as rs139055077; called by muse, mutect2, varscan2
- HECW1 | c.2232C>T p.S744= | Silent (SNP) | VAF 25/47 reads (53%) | catalogued as COSV101224118; called by muse, mutect2, varscan2
- ITPR2 | c.7053G>A p.A2351= | Silent (SNP) | VAF 106/434 reads (24%) | catalogued as rs770297282, COSV67276139; called by muse, mutect2, varscan2
- KIAA1522 | c.2931C>T p.P977= (on ENST00000373480 / NM_001198972.2; = p.P1036= on NM_020888.3) | Silent (SNP) | VAF 17/64 reads (27%) | catalogued as rs374181893, COSV53864893, COSV99614919; called by muse, mutect2, varscan2
- LAMA5 | c.5259G>T p.T1753= | Silent (SNP) | VAF 90/323 reads (28%) | catalogued as rs202112441, COSV99441382; called by muse, varscan2
- LRWD1 | c.744G>A p.A248= | Silent (SNP) | VAF 20/84 reads (24%) | catalogued as rs764974125, COSV52961185, COSV99479463; called by muse, mutect2, varscan2
- POTEA | c.243G>A p.A81= | Silent (SNP) | VAF 53/206 reads (26%) | catalogued as rs1366568302; called by muse, mutect2, varscan2
- RNF215 | c.831G>A p.A277= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as rs755036120, COSV99306647; called by muse, mutect2, varscan2
